Somatic mutation profile of tumor specimen C3L-06369-57 (aliquot CPT0413490002) from CPTAC case C3L-06369, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 75.3 years (27,521 days).
Specimen C3L-06369-57: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31e1e353-eac3-4f6b-b1dd-82605dd650b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06369-50 (Buccal Cell Normal), aliquot CPT0413430001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a7714fd-0ca3-4161-a9a3-b02ae4c5b6a3

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>C p.K117N | Missense Mutation (SNP) | VAF 68/215 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 20/93 reads (22%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- C11orf95 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1322867067; called by muse, mutect2, varscan2
- EVA1A | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 144/369 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52057497; called by muse, mutect2, varscan2
- PEG3 | c.3901G>A p.V1301I | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs1253910557, COSV55624930, COSV55641124; called by muse, mutect2
- GMPPB | c.201G>C p.Q67H | Missense Mutation (SNP) | VAF 118/286 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RELCH | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 93/226 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ATG16L2 | c.825-312C>T | Intron (SNP) | VAF 82/188 reads (44%) | catalogued as rs1018726774; called by muse, mutect2, varscan2
